CCDI case PBBVBH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/23871a2d-5637-4fe3-b799-0584f0592ee9

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Astroblastoma: ICD-O-3 morphology code: 9430/3; Tissue or organ of origin: Cerebrum; Age at diagnosis: 11.7 years (4,261 days).

Biospecimens (3 samples)
- Sample 0DI3IV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI3JC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI3NF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
